Gene-level copy-number profile of tumor specimen TARGET-40-PAPFLB-01A from TARGET case TARGET-40-PAPFLB, project TARGET-OS (Osteosarcoma). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 15.0 years (5,496 days).
Specimen TARGET-40-PAPFLB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.31930492-144d-50cd-8611-931abd612381.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAPFLB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 463 have no estimate.
https://portal.gdc.cancer.gov/files/69dc1513-2747-4aac-9db4-e52006c1306f

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 1,180; copy number 1: 28,843; copy number 2: 26,327; copy number 3: 1,884; copy number 4: 933; copy number 5: 178; copy number 6: 299; copy number 7: 313; copy number 8: 91; copy number 9: 8; copy number 11: 10; copy number 12: 94.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:72,749,277–72,861,914, 1 gene (within-gene range 0–1): SHQ1.
- chr3:72,876,737–73,069,198, 8 genes: PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2.
- chr3:116,582,552–116,965,227, 8 genes: RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr6:88,609,897–88,963,618, 2 genes (within-gene range 0–1): RNGTT, SNORA73.
- chr9:122,567,117–122,583,384, 1 gene (within-gene range 0–1): OR1L8.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr13:48,232,612–49,528,981, 29 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,772 genes in 67 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–827,796, 30 genes, copy number 3–4 (within-gene range 1–4): OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AL669831.3, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2.
- chr1:56,145,721–59,810,647, 44 genes, copy number 3 (within-gene range 1–3): AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2, FYB2, AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY.
- chr1:87,212,669–114,995,370, 517 genes, copy number 3–5 (within-gene range 1–5) (broad region; genes not listed).
- chr1:118,883,046–121,580,524, 78 genes, copy number 3 (broad region; genes not listed).
- chr1:149,782,671–150,809,577, 58 genes, copy number 4: FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3.
- chr2:88,857,161–89,268,506, 41 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr4:49,203,171–49,589,529, 19 genes, copy number 8: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:121,542,486–129,861,547, 92 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr6:130,133,410–135,497,765, 107 genes, copy number 4 (broad region; genes not listed).
- chr7:70,972–9,189,857, 207 genes, copy number 3–4 (broad region; genes not listed).
- chr7:10,973,336–21,945,903, 118 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:22,563,337–25,266,290, 60 genes, copy number 5–9: AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3.
- chr7:26,398,593–27,212,965, 50 genes, copy number 6 (within-gene range 1–6): AC004540.1, KIAA0087, AC004947.2, AC004947.1, AC004947.3, LINC02860, SKAP2, RPL7AP38, HMGB3P20, TPM3P4, NHP2P2, HOXA1, HOTAIRM1, AC004079.3, AC004079.4, AC004079.2, AC004079.1, AC004079.5, HOXA2, HOXA3, HOXA-AS2, HOXA4, AC004080.6, HOXA-AS3, HOXA5, HOXA6, AC004080.5, HOXA7, AC004080.4, HOXA9, AC004080.3, HOXA10-AS, MIR196B, HOXA10, HOXA11, HOXA11-AS, AC004080.7, AC004080.14, AC004080.8, AC004080.2, AC004080.12, AC004080.15, AC004080.13, HOXA13, HOTTIP, AC004080.9, AC004080.16, AC004080.10, AC004080.11, AC004080.17.
- chr7:34,658,218–35,697,459, 17 genes, copy number 7 (within-gene range 1–7): NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N, AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2.
- chr7:53,316,149–54,812,727, 24 genes, copy number 4 (within-gene range 1–4): RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT.
- chr8:12,628,476–12,719,190, 9 genes, copy number 3: RPS3AP35, AC068587.3, AC068587.7, AC068587.5, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2.
- chr8:87,788,562–93,029,839, 60 genes, copy number 3: SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084.
- chr8:97,241,742–98,117,171, 19 genes, copy number 3: AP003115.1, TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA.
- chr8:108,443,601–119,673,453, 89 genes, copy number 3–5 (broad region; genes not listed).
- chr8:120,052,180–133,814,537, 206 genes, copy number 3–4 (broad region; genes not listed).
- chr9:60,914,407–68,644,442, 177 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr10:52,389,112–53,458,288, 10 genes, copy number 3: RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318.
- chr11:101,890,674–104,682,581, 56 genes, copy number 3: ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1.
- chr11:129,863,636–133,956,968, 54 genes, copy number 3: NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, AP003486.2, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697.
- chr13:18,467,172–20,525,873, 69 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr13:99,200,774–101,720,856, 45 genes, copy number 3 (within-gene range 1–3): UBAC2, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4, CCR12P, AL136961.1, TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8, AL139035.2, CLYBL, MIR4306, CLYBL-AS2, CLYBL-AS1, AL137139.1, AL137139.3, AL137139.2, ZIC5, AL355338.1, ZIC2, LINC00554, NDUFA12P1, PCCA-DT, ASNSP3, PCCA, RPL15P18, AL356575.1, AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6, NALCN-AS1, ARF4P3, LINC00411, NALCN, ITGBL1.
- chr13:104,125,930–114,337,626, 163 genes, copy number 3–12 (broad region; genes not listed).
- chr14:105,785,505–106,369,546, 103 genes, copy number 4 (broad region; genes not listed).
- chr15:25,056,860–25,085,476, 16 genes, copy number 6: SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15, SNORD116-16, SNORD116-17, SNORD116-18.
- chr15:52,755,053–55,092,177, 16 genes, copy number 3: ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490, AC066614.1, WDR72, RNU2-53P, RNU6-449P, AC084759.1, AC084759.3, AC084759.2, UNC13C, AC010867.1, HNRNPA1P74, AC025272.1.
- chr15:96,783,389–98,293,199, 23 genes, copy number 3 (within-gene range 2–3): SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2.
- chr17:7,686,071–14,957,216, 169 genes, copy number 3–8 (broad region; genes not listed).
- chr17:15,229,773–27,170,310, 397 genes, copy number 3–12 (broad region; genes not listed).
- chr17:48,294,335–53,106,358, 171 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr17:54,609,249–56,595,611, 25 genes, copy number 3: AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2, RPL39P33, NOG.
- chr17:58,897,776–60,030,746, 45 genes, copy number 6: AC100832.1, Metazoa_SRP, AC100832.2, TRIM37, RN7SL716P, AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17, YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3.
- chr17:62,627,670–66,278,664, 122 genes, copy number 3 (broad region; genes not listed).
- chr17:67,070,444–72,237,203, 97 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr20:87,250–2,453,117, 73 genes, copy number 3 (broad region; genes not listed).
- chr22:16,405,330–16,698,742, 17 genes, copy number 3 (within-gene range 2–3): AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3.

Autosomal genes at a single copy (total copy number 1): 27,473. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
